Surgical pathology report (de-identified scan), TCGA case TCGA-ZX-AA5X, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Alabama, specimen TCGA-ZX-AA5X-01A (Primary Tumor).

Cervical Tumor
Whole Blood

Collected date:

Surgical Pathology Final Report

Diagnosis

Uterus, cervix, biopsy:- Squamous cell carcinoma, moderately differentiated, invasive.

Clinical Information

The patient is a -year-old female with clinical III-b cervical cancer.

Gross Description

The specimen is received in a single container labeled "cervical biopsy." Received are two fragments of tan pink tissue measuring from 0.3 cm to 0.5 cm in greatest dimensions, submitted in total.

Block Summary

A1- Cervical biopsy.

ICD O-3
Carcinoma, squamous cell NOS 8072/3
Site Cervix C53.9
JW 5/19/14

Microscopic Description

A microscopic examination has been performed.

Dual/Synchronous Primary		Noted

Source: NCI Genomic Data Commons file a9749cbc-8c59-4c87-892f-d15c1b562a2c (TCGA-ZX-AA5X.AFCAEB29-0F3E-48E6-8F0D-92860BCF0640.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).